TARGET case TARGET-20-D84-Myeloid-CBFA2T3_GLIS2-2 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/fc295de5-8557-4d50-b57e-1095652f6b86

Biospecimens (1 sample)
- Sample TARGET-20-D84-Myeloid-CBFA2T3_GLIS2-2-85: Sample type: Next Generation Cancer Model; Tissue type: Tumor.
